Gene-level copy-number profile of tumor specimen TCGA-43-A475-01A from TCGA case TCGA-43-A475, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.6 years (24,680 days).
Specimen TCGA-43-A475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b4b3d475-1af1-45f9-acd6-06a2f4006d4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-A475-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49580887-f4dc-436e-b178-73a6e662370f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,686; copy number 3: 170; copy number 4: 28,596; copy number 5: 1,595; copy number 6: 16,444; copy number 7: 2,082; copy number 8: 5,942; copy number 10: 633; copy number 11: 22; copy number 12: 24; copy number 15: 612; copy number 77: 3; copy number 90: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-A475-01A-11D-A24C-01): tumor purity 0.34, ploidy 2.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,297 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,670,878–198,222,513, 636 genes, copy number 12–15 (broad region; genes not listed).
- chr6:41,934,934–42,050,357, 3 genes, copy number 77 (within-gene range 4–77): CCND3, RNU6-761P, AL513008.1.
- chr6:110,341,973–110,415,575, 2 genes, copy number 90: AL050350.1, DDO.
- chr6:110,439,996–110,440,303, 1 gene, copy number 90: RN7SL617P.
- chr8:40,900,016–41,896,762, 22 genes, copy number 11 (within-gene range 4–11): AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1.
- chr12:66,767–23,251,499, 632 genes, copy number 10 (broad region; genes not listed).
- chr12:23,637,973–23,638,487, 1 gene, copy number 10: AC087260.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
